TCGA case TCGA-HT-7616 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western - St Joes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab24cdc3-74a1-443f-831f-b7fb3821de6a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 7 days.

Diagnoses (1)
1. Oligodendroglioma, anaplastic: ICD-O-3 morphology code: 9451/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 75.8 years (27,685 days); Year of diagnosis: 2007; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Antiseizure Treatment, preoperative; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; adjuvant Radiation Therapy, NOS; Steroid Therapy, preoperative.

Follow-up (1 entry)
- Days to follow up: 7 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Altered Mental Status / Motor / Movement Change / Seizure.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HT-7616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-HT-7616-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-HT-7616-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-HT-7616-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HT-7616-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: Yes; History headaches: No; Symp changes mental status: Yes; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: Yes; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Follow-up form: Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 7 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 7 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 7 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HT-7616-01A-11D-2252-01): tumor purity 0.79, ploidy 1.89, whole-genome doublings 0.
